Somatic mutation profile of tumor specimen MMRF_1205_2_BM_CD138pos (aliquot MMRF_1205_2_BM_CD138pos_T1_KBS5U_L06431) from MMRF case MMRF_1205, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 79.0 years (28,843 days).
Specimen MMRF_1205_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af08598b-33db-415e-80c5-2ea5020c77f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1205_2_PB_Whole (Blood Derived Normal), aliquot MMRF_1205_2_PB_Whole_C3_KBS5U_L06476; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/efc2aba9-c5cf-4598-9976-b085b76e63a6

The open-access MAF lists 117 somatic variants for this specimen: 43 protein-altering or splice-affecting, 9 silent, 65 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 38, Missense Mutation 34, Intron 18, Silent 9, 3'Flank 4, Frame Shift Del 3, RNA 3, Nonsense Mutation 2, Splice Site 2, 5'Flank 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 31/71 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CES3 | c.287+3G>T | Splice Region (SNP) | VAF 33/93 reads (35%) | catalogued as COSV57595040; called by muse, mutect2, varscan2
- CNTNAP2 | c.553del p.X185_splice | Splice Site (DEL) | VAF 16/44 reads (36%) | catalogued as COSV62265291; called by mutect2, varscan2
- DENND4C | c.2474T>C p.V825A | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100991282; called by muse, mutect2, varscan2
- IGHD7-27 | c.1C>G p.L1V | Missense Mutation (SNP) | VAF 16/19 reads (84%) | PolyPhen probably damaging (0.998); catalogued as rs561109248; called by muse, mutect2, varscan2
- KMT2D | c.11212C>T p.Q3738* | Nonsense Mutation (SNP) | VAF 28/73 reads (38%) | catalogued as COSV99040365; called by muse, mutect2, varscan2
- MUC16 | c.20870G>A p.S6957N | Missense Mutation (SNP) | VAF 95/177 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs766333222, COSV67487670; called by muse, mutect2, varscan2
- MYH4 | c.1783G>T p.G595C | Missense Mutation (SNP) | VAF 60/184 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs571679462; called by muse, mutect2, varscan2
- NOTCH3 | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as rs574575017; called by muse, mutect2, varscan2
- OBSCN | c.13424C>T p.P4475L | Missense Mutation (SNP) | VAF 46/64 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs376692462; called by muse, mutect2
- SDK1 | c.2056G>A p.V686M | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs756716734; called by muse, mutect2, varscan2
- SIPA1L1 | c.2611G>A p.A871T | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as rs1297000256; called by muse, mutect2, varscan2
- SULT1C3 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0.014); catalogued as rs367742535; called by muse, mutect2, varscan2
- TWNK | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs1364676852, COSV52966051; called by muse, mutect2, varscan2
- UNC5B | c.2095G>A p.V699I | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141426412; called by muse, mutect2, varscan2
- ZNF341 | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1478366832; called by muse, mutect2, varscan2
- AC131160.1 | c.923C>G p.A308G | Missense Mutation (SNP) | VAF 66/256 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- ANKRD33B | c.813del p.K272Sfs*20 | Frame Shift Del (DEL) | VAF 21/96 reads (22%) | called by mutect2, pindel, varscan2
- ARAP2 | c.4633G>T p.A1545S | Missense Mutation (SNP) | VAF 105/191 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CES2 | c.954C>A p.F318L | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CLTCL1 | c.4615C>A p.Q1539K (on ENST00000427926 / NM_007098.4; = p.Q1482K on NM_001835.4) | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- FAM184A | c.2849T>A p.I950N | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- H2BC10 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- KAT6A | c.5531G>A p.R1844K | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- KAT6B | c.2402G>T p.C801F | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LAMA1 | c.6135G>T p.R2045S | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LZIC | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 74/201 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MAU2 | c.972_973+3del p.X324_splice | Splice Site (DEL) | VAF 54/107 reads (50%) | called by mutect2, pindel, varscan2
- PCDHB14 | c.623T>G p.L208R | Missense Mutation (SNP) | VAF 133/276 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- PKHD1 | c.4114C>T p.Q1372* | Nonsense Mutation (SNP) | VAF 57/144 reads (40%) | called by muse, mutect2, varscan2
- POLR2A | c.2446G>A p.G816R | Missense Mutation (SNP) | VAF 65/183 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RCN3 | c.580C>G p.P194A | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SPACA6 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- STK11IP | c.2686C>T p.H896Y | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TMEFF1 | c.1108C>A p.H370N | Missense Mutation (SNP) | VAF 92/330 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRPC4 | c.2514dup p.V839Cfs*12 (on ENST00000379705 / NM_016179.4; = p.V844Cfs*12 on NM_003306.3) | Frame Shift Ins (INS) | VAF 40/130 reads (31%) | called by mutect2, pindel, varscan2
- TSPEAR | c.1787A>G p.E596G | Missense Mutation (SNP) | VAF 61/253 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- UBR4 | c.12007A>T p.I4003F | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- VPS35 | c.812del p.P271Lfs*9 | Frame Shift Del (DEL) | VAF 11/19 reads (58%) | called by mutect2, pindel, varscan2
- ZDHHC5 | c.1090T>A p.S364T | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZNF608 | c.3787_3790del p.E1263Rfs*3 | Frame Shift Del (DEL) | VAF 52/309 reads (17%) | called by mutect2, pindel, varscan2
- ZNF729 | c.1706A>T p.E569V | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- ZNF79 | c.571A>G p.K191E | Missense Mutation (SNP) | VAF 58/262 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- FDPS | c.789C>G p.V263= | Silent (SNP) | VAF 11/85 reads (13%) | called by muse, mutect2
- GIMAP7 | c.228C>A p.T76= | Silent (SNP) | VAF 49/159 reads (31%) | called by muse, mutect2, varscan2
- GSC | c.132C>T p.Y44= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs1446826320; called by muse, mutect2, varscan2
- H1-4 | c.282G>A p.V94= | Silent (SNP) | VAF 44/121 reads (36%) | catalogued as rs549787183, COSV99175207; called by muse, mutect2, varscan2
- KCNJ15 | c.666C>A p.T222= | Silent (SNP) | VAF 144/284 reads (51%) | called by muse, mutect2, varscan2
- PCDH19 | c.3150C>T p.S1050= (on ENST00000373034 / NM_001184880.2; = p.S1002= on NM_020766.3) | Silent (SNP) | VAF 43/58 reads (74%) | called by muse, mutect2, varscan2
- PGR | c.45G>A p.A15= | Silent (SNP) | VAF 32/117 reads (27%) | catalogued as rs1464743270; called by muse, mutect2, varscan2
- SI | c.1629A>T p.T543= | Silent (SNP) | VAF 36/140 reads (26%) | called by muse, mutect2, varscan2
- TYW3 | c.510G>T p.L170= | Silent (SNP) | VAF 24/89 reads (27%) | called by muse, mutect2, varscan2
- AC011525.1 | n.885T>A | RNA (SNP) | VAF 54/187 reads (29%) | called by muse, mutect2, varscan2
- AIMP1 | c.*129T>G | 3'UTR (SNP) | VAF 20/104 reads (19%) | catalogued as rs996070126; called by muse, mutect2, varscan2
- ALDH1A2 | c.117+104C>T | Intron (SNP) | VAF 15/95 reads (16%) | called by muse, mutect2, varscan2
- ANP32A | c.625-75G>C | Intron (SNP) | VAF 51/123 reads (41%) | called by muse, mutect2, varscan2
- ARHGAP21 | c.*743_*744del | 3'UTR (DEL) | VAF 82/264 reads (31%) | called by pindel, varscan2
- BRF1 | c.789-927G>T | Intron (SNP) | VAF 42/114 reads (37%) | called by muse, mutect2, varscan2
- C16orf89 | c.*353A>C | 3'UTR (SNP) | VAF 20/41 reads (49%) | called by muse, mutect2, varscan2
- C1GALT1C1L | c.*16A>T | 3'UTR (SNP) | VAF 15/49 reads (31%) | called by muse, varscan2
- C1orf116 | c.*2313A>G | 3'UTR (SNP) | VAF 27/109 reads (25%) | called by muse, mutect2, varscan2
- C1orf131 | c.747-90G>T | Intron (SNP) | VAF 7/82 reads (9%) | called by muse, mutect2
- C1orf198 | c.*119T>G | 3'UTR (SNP) | VAF 10/144 reads (7%) | called by muse, mutect2
- CAPZA2 | c.*685A>C | 3'UTR (SNP) | VAF 17/43 reads (40%) | called by muse, mutect2, varscan2
- CARD8 | c.*8C>T | 3'UTR (SNP) | VAF 40/166 reads (24%) | called by muse, mutect2, varscan2
- CDV3 | c.*1184A>G | 3'UTR (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- CEP135 | c.1044+107G>A | Intron (SNP) | VAF 28/77 reads (36%) | catalogued as rs547293325; called by muse, mutect2, varscan2
- CES3 | c.83-105G>T | Intron (SNP) | VAF 42/94 reads (45%) | catalogued as rs771168871; called by muse, varscan2
- CTBP1 | c.41-2998A>T | Intron (SNP) | VAF 65/223 reads (29%) | called by muse, mutect2, varscan2
- DIP2A | c.*6G>C | 3'UTR (SNP) | VAF 31/105 reads (30%) | called by muse, mutect2, varscan2
- DISC1 | c.*1259T>G | 3'UTR (SNP) | VAF 84/107 reads (79%) | called by muse, mutect2, varscan2
- DST | c.4297-2829G>T | Intron (SNP) | VAF 90/243 reads (37%) | called by muse, mutect2, varscan2
- ETV1 | chr7:13893927 G>A | 3'Flank (SNP) | VAF 19/49 reads (39%) | catalogued as rs540868797; called by muse, mutect2, varscan2
- FAM122B | c.*1717G>A | 3'UTR (SNP) | VAF 23/63 reads (37%) | called by muse, mutect2, varscan2
- FAM171A1 | c.*267G>A | 3'UTR (SNP) | VAF 41/115 reads (36%) | catalogued as rs769900543; called by muse, mutect2, varscan2
- GEM | c.*480A>C | 3'UTR (SNP) | VAF 23/66 reads (35%) | called by muse, mutect2, varscan2
- GRIN2A | c.*6852_*6853del | 3'UTR (DEL) | VAF 28/87 reads (32%) | called by mutect2, pindel, varscan2
- GTPBP8 | c.*845G>A | 3'UTR (SNP) | VAF 44/176 reads (25%) | called by muse, mutect2, varscan2
- HGSNAT | c.*394A>G | 3'UTR (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- IGLL5 | c.-91A>G | 5'UTR (SNP) | VAF 59/67 reads (88%) | called by muse, mutect2, varscan2
- ISL1 | c.219-1106del | Intron (DEL) | VAF 24/102 reads (24%) | called by mutect2, varscan2*
- ITGA1 | c.*2727T>C | 3'UTR (SNP) | VAF 46/126 reads (37%) | called by muse, mutect2, varscan2
- KLHL1 | c.*803C>T | 3'UTR (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- KRT73 | c.*198C>A | 3'UTR (SNP) | VAF 23/57 reads (40%) | called by muse, mutect2, varscan2
- LBX2 | chr2:74503161 G>A | 5'Flank (SNP) | VAF 85/191 reads (45%) | called by muse, mutect2, varscan2
- MAML1 | c.*2076C>T | 3'UTR (SNP) | VAF 31/89 reads (35%) | called by muse, mutect2, varscan2
- MDGA1 | c.2776+54C>T | Intron (SNP) | VAF 253/450 reads (56%) | catalogued as rs1418108609, COSV51801465; called by muse, mutect2, varscan2
- MEIS2 | c.1147+393T>C | Intron (SNP) | VAF 136/604 reads (23%) | called by muse, mutect2, varscan2
- MLST8 | c.699-32G>A | Intron (SNP) | VAF 51/126 reads (40%) | called by muse, mutect2, varscan2
- MNS1 | c.*52T>G | 3'UTR (SNP) | VAF 40/214 reads (19%) | called by muse, varscan2
- MYL6B | c.520+150T>C | Intron (SNP) | VAF 31/77 reads (40%) | called by muse, mutect2, varscan2
- Metazoa_SRP | chr15:62243484 C>A | 3'Flank (SNP) | VAF 73/292 reads (25%) | called by muse, mutect2, varscan2
- NCOA3 | c.*2087T>C | 3'UTR (SNP) | VAF 29/77 reads (38%) | called by muse, mutect2, varscan2
- NME6 | c.-7-679T>G | Intron (SNP) | VAF 16/66 reads (24%) | called by muse, mutect2, varscan2
- NRP1 | c.1864+200T>G | Intron (SNP) | VAF 30/76 reads (39%) | called by muse, mutect2, varscan2
- ONECUT2 | c.*2225G>T | 3'UTR (SNP) | VAF 28/68 reads (41%) | called by muse, mutect2, varscan2
- PANK2 | chr20:3924864 C>T | 3'Flank (SNP) | VAF 68/158 reads (43%) | called by muse, mutect2, varscan2
- PFDN1 | c.*174T>G | 3'UTR (SNP) | VAF 89/161 reads (55%) | called by muse, mutect2, varscan2
- PIFO | c.*1128A>G | 3'UTR (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- PLCB4 | c.*31C>T | 3'UTR (SNP) | VAF 110/353 reads (31%) | catalogued as rs1432167828, COSV99594741; called by muse, mutect2, varscan2
- PPP4R1 | c.*514C>T | 3'UTR (SNP) | VAF 40/102 reads (39%) | catalogued as rs1405632344; called by muse, mutect2, varscan2
- RIMBP2 | c.*2710G>T | 3'UTR (SNP) | VAF 35/107 reads (33%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.1637C>G | RNA (SNP) | VAF 23/72 reads (32%) | called by muse, mutect2, varscan2
- SERPINE2 | c.*343G>A | 3'UTR (SNP) | VAF 33/76 reads (43%) | catalogued as rs1272345840; called by muse, mutect2, varscan2
- SET | c.*1311A>C | 3'UTR (SNP) | VAF 133/388 reads (34%) | called by muse, mutect2, varscan2
- SPHKAP | c.*336G>A | 3'UTR (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- THSD4 | c.*347A>G | 3'UTR (SNP) | VAF 50/109 reads (46%) | called by muse, mutect2, varscan2
- TIA1 | c.*1873T>G | 3'UTR (SNP) | VAF 29/70 reads (41%) | called by muse, mutect2, varscan2
- TLN2 | c.-36-9418C>T | Intron (SNP) | VAF 47/103 reads (46%) | catalogued as rs911285830; called by muse, mutect2, varscan2
- TMEM185B | c.*676C>T | 3'UTR (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2
- TMEM267 | c.*405T>C | 3'UTR (SNP) | VAF 47/114 reads (41%) | called by muse, mutect2, varscan2
- TMEM99 | n.682T>G | RNA (SNP) | VAF 49/145 reads (34%) | called by muse, mutect2, varscan2
- TXNRD1 | c.305-1957A>T | Intron (SNP) | VAF 67/167 reads (40%) | catalogued as COSV61597654; called by muse, mutect2, varscan2
- UVSSA | chr4:1392779 T>C | 3'Flank (SNP) | VAF 16/76 reads (21%) | called by muse, mutect2
- VGLL3 | c.*8738C>T | 3'UTR (SNP) | VAF 34/155 reads (22%) | called by muse, mutect2, varscan2
- VPS39 | c.139+300_139+312del | Intron (DEL) | VAF 24/76 reads (32%) | called by mutect2, pindel
- ZFYVE27 | c.*1174G>A | 3'UTR (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
